Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3UD, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3UD-01A (Primary Tumor).

[page 1 of 4]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

* Amended *

Patient: [REDACTED]

CC:

Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Back pain and mass growing from left renal vein.

Specimens Submitted:

- 1: SP: Left radical nephrectomy (left renal leiomyosarcoma)
- 2: SP: Left adrenal gland

AMENDED DIAGNOSIS:

1. LEFT RADICAL NEPHRECTOMY:
- HIGH GRADE LEIOMYOSARCOMA, 8.5 CM, INVOLVING THE RENAL VEIN
- A SEPARATE NODULAR FOCUS OF TUMOR, 0.9 CM, IS PRESENT ADJACENT TO A LARGE VESSEL IN THE RENAL HILUM
- THE MITOTIC RATE IS UP TO 12 MITOSES PER 10 HIGH POWER FIELDS
- COAGULATIVE NECROSIS AND DIFFUSE ATYPIA ARE PRESENT
- BENIGN KIDNEY AND PORTION OF ADRENAL GLAND

NOTE: IN THE SPECIMEN RECEIVED, TUMOR IS PRESENT IN THE RENAL VEIN AT THE SURGICAL RESECTION MARGIN, HOWEVER AS IT IS FREE FLOATING AND NOT ATTACHED TO THE VESSEL WALL, IT MAY NOT REPRESENT A TRUE POSITIVE MARGIN. CLINICAL CORRELATION IS RECOMMENDED.

2. LEFT ADRENAL GLAND:
- BENIGN ADRENAL GLAND

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED] That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:

DIAGNOSIS:

1. LEFT RADICAL NEPHRECTOMY:
- HIGH GRADE LEIOMYOSARCOMA, 8.5 CM, INVOLVING THE RENAL VEIN
- TUMOR IS PRESENT AT THE RENAL VEIN MARGIN
- A SEPARATE NODULAR FOCUS OF TUMOR, 0.9 CM, IS PRESENT ADJACENT TO A LARGE VESSEL IN THE RENAL HILUM

AMENDED REPORT:

** Continued on next page **

ICD-O3

leiomyosarcoma, NOS
8890/3

Site:

path: Vein, NOS C49.9

CCF: Retroperitoneum C48.0

5-2-12

Ro

[page 2 of 4]
SURGICAL

Page 2 of 4

DIAGNOSIS:

1. LEFT RADICAL NEPHRECTOMY:

- HIGH GRADE LEIOMYOSARCOMA, 8.5 CM, INVOLVING THE RENAL VEIN
- A SEPARATE NODULAR FOCUS OF TUMOR, 0.9 CM, IS PRESENT ADJACENT TO A LARGE VESSEL IN THE RENAL HILUM

NOTE: IN THE SPECIMEN RECEIVED, TUMOR IS PRESENT IN THE RENAL VEIN AT THE SURGICAL RESECTION MARGIN, HOWEVER AS IT IS FREE FLOATING AND NOT ATTACHED TO THE VESSEL WALL, IT MAY NOT REPRESENT A TRUE POSITIVE MARGIN. CLINICAL CORRELATION IS RECOMMENDED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is received fresh labeled "left radical nephrectomy (left renal leiomyosarcoma)" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 476.5 g in total. The kidney measures 12.7 x 6.5 x 3.7 cm. The attached ureter measures 2.3 cm in length and 0.3 cm in diameter. The attached renal vein measures 8.3 cm in length and 2.6 cm in diameter. The renal vein margin is grossly involved by tumor. Ureter margin is grossly unremarkable. A portion of adrenal gland measuring 1.6 x 0.9 x 0.6 cm is identified. The renal vein is inked black and bivalved to reveal a 8.5 x 4.3 x 3.5 cm multinodular firm tan mass filling and expanding the renal vein. The mass is 2.5 cm from the renal hilum and 1.0 cm from the adrenal gland. Sections through the kidney shows a cyst measuring 3 x 2.5 x 2.5 cm in the lower pelvis. The remainder of the kidney reveals a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.9 cm and the calyces appear normal. A possible lymph node measuring 0.9 cm is identified in the hilum. Representative sections are submitted for TPS and for permanent sections. Photo is taken.

Summary of sections:

RVM renal vein margin
UVM ureteral and other vessel margin
A adrenal gland
LN possible lymph node
T-- tumor
RP -- renal pelvis representative sections
K -- representative sections kidney
C renal cyst, representative

** Continued on next page **

[page 3 of 4]
SURGICAL

----- Page 3 of 4

2). The specimen is received fresh, labeled, "left adrenal gland" and consists of a 5.5 x 2.4 x 1.5 cm portion of red-pink to yellow-tan, lobulated fibroadipose tissue with a staple line. Sectioning reveals a 24 x 2.8 x 0.9 cm triangular, yellow-orange adrenal with no gross lesions. Representative sections are submitted in three cassettes.

Summary of sections:
U undesignated

Summary of Sections:

Part 1: SP: Left radical nephrectomy (left renal leiomyosarcoma)

Block	Sect.	Site	PCs
1	a		1
2	c		2
1	k		1
1	ln		1
1	rp		1
1	rvn		1
7	t		7
1	uvm		2

Part 2: SP: Left adrenal gland

Block	Sect.	Site	PCs
3	U		4

Amendments

Amend Date: Amended By:

Original Diagnosis:

1. LEFT RADICAL NEPHRECTOMY:
- HIGH GRADE LEIOMYOSARCOMA, 8.5 CM, INVOLVING THE RENAL VEIN
- TUMOR IS PRESENT AT THE RENAL VEIN MARGIN
- A SEPARATE NODULAR FOCUS OF TUMOR, 0.9 CM, IS PRESENT ADJACENT TO A LARGE VESSEL IN THE RENAL HILUM
- THE MITOTIC RATE IS UP TO 12 MITOSES PER 10 HIGH POWER FIELDS
- COAGULATIVE NECROSIS AND DIFFUSE ATYPIA ARE PRESENT
- BENIGN KIDNEY AND PORTION OF ADRENAL GLAND
2. LEFT ADRENAL GLAND:
- BENIGN ADRENAL GLAND

** Continued on next page **

[page 4 of 4]
SURGICAL

Page 4 of 4

*** Report Electronically Signed Out ***
Signed out by

Intraoperative Consultation:

WAS NOTIFIED VIA TELEPHONE ON ..

AS NOTIFIED VIA TELEPHONE ON

** End of Report **

Source: NCI Genomic Data Commons file 34b3397c-be07-428b-97c2-282abff7648a (TCGA-DX-A3UD.9BCF6B63-F489-47D2-A46C-62E78598F2B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).